Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8013, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8013-01A (Primary Tumor).

Microscopic

Sections demonstrate a moderately cellular proliferation of neoplastic astrocytes, primarily with gemistocytic features. Pleomorphism is prominent in areas. Focal areas of neoplastic oligodendrocytes are also present. There is no evidence of microvascular proliferation. Mitotic figures are not seen. However, several large foci of necrosis without pseudopalisading are present.

Addendum

MIB-1 stain demonstrates scattered reactive cells. It also identifies a rare mitotic figure. The MIB-1 labeling index of 2.2% is indicative of a modestly proliferative tumor.

Diagnosis

Oligoastrocytoma, astrocytoma predominant, grade II

Source: NCI Genomic Data Commons file 994636a9-d75c-4c4f-bb1b-8516dee079d5 (TCGA-HT-8013.9F364B5B-EAD4-42A4-A802-F398E08F1DFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).